Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5100, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5100-01A (Primary Tumor).

FINAL DIAGNOSIS

KIDNEY, RIGHT (430 GRAMS), RADICAL NEPHRECTOMY -

- A. MULTICENTRIC RENAL CELL CARCINOMA, CLEAR CELL VARIANT (DOMINANT MASS 8.0 CM, ADDITIONAL 4.0 CM MASS, SMALLER 0.2-0.3 CM CYSTIC MASSES).
- 1. FUHRMAN NUCLEAR GRADE 3.
- 2. BOTH LARGE NODULES EXTEND INTO RENAL CAPSULE, BUT WITHOUT PENETRATION THROUGH THE CAPSULE INTO PERINEPHRIC FAT.
- 3. TUMOR EXTENDS INTO RENAL VEIN.
- 4. HILAR VASCULAR AND URETERIC MARGINS ARE FREE OF TUMOR.
- 5. RENAL PELVIS UNINVOLVED BY TUMOR.
- B. PATHOLOGIC GRADE T3NXMX (see comment).
- C. ADRENAL GLAND UNINVOLVED BY TUMOR.
- D. CHRONIC INTERSTITIAL NEPHRITIS AND SEVERE ARTERIO AND ARTERIOLOSCLEROSIS (see comment).

Source: NCI Genomic Data Commons file 38017306-ad9c-4947-bb30-2d5fad5d9eb4 (TCGA-B0-5100.7C3CF3B9-1B20-4362-97E7-DEE72E9CE2A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).